Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A42E, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A42E-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, LEFT PELVIC, EXCISION -

TWO (2) BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA.

PART 2: LYMPH NODES, RIGHT PELVIC, EXCISION -

THREE (3) BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA.

PART 3: URETHRA, MARGIN -

- BENIGN UROTHELIUM AND UNDERLYING SUBMUCOSA WITH REACTIVE CHANGES.
- BENIGN PROSTATIC TISSUE.

PART 4: URINARY BLADDER, PROSTATE AND SEMINAL VESICLES, CYSTOPROSTATECTOMY AND NEOBLADDER CONSTRUCTION -

FOR THE URINARY BLADDER:

- INVASIVE HIGH GRADE PAPILLARY UROTHELIAL CARCINOMA. < 9% per TSS
- THE CARCINOMA HAS FEATURES OF LYMPHOEPITHELIOMA-LIKE CARCINOMA AND FOCI OF SQUAMOUS DIFFERENTIATION.
- THE CARCINOMA MEASURES 6.5 CM IN GREATEST DIMENSION.
- THE CARCINOMA IS LOCATED IN POSTERIOR TO RIGHT LATERAL BLADDER WALL.
- THE CARCINOMA EXTENDS THROUGH DETRUSOR MUSCLE AND INVOLVING THE PERIVESICULAR SOFT TISSUE.
- ALL SURGICAL MARGINS ARE NEGATIVE FOR TUMOR.
- EXTENSIVE BIOPSY SITE CHANGES ARE PRESENT.
- LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- PATHOLOGIC STAGE: pT3aN0MX.
- BENIGN PROSTATIC TISSUE.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystoprostatectomy
TUMOR SITE: Right lateral wall, Posterior wall
TUMOR SIZE: Greatest dimension: 6.5 cm
HISTOLOGIC TYPE: Urothelial (transitional cell) carcinoma
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Papillary, Solid/nodule, Flat
PATHOLOGIC STAGING (pTNM): pT3a
pN0

Number of nodes examined: 5

pMX

MARGINS: Margins uninvolved by invasive carcinoma

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Absent

DIRECT EXTENSION OF INVASIVE TUMOR: Perivesical fat

ADDITIONAL PATHOLOGIC FINDINGS: Urothelial dysplasia (low-grade intraurothelial neoplasia)
Therapy-related changes

ICD-O-3

urothelial carcinoma,
papillary 8120/3

Site:

path: bladder, wall, NOS
C67.9

C67.9: bladder, wall,
posterior C67.4

9-1-12

RD

Source: NCI Genomic Data Commons file 8c19a414-fac0-4922-9365-8f2c1bc5922c (TCGA-BT-A42E.5613DDA8-5440-428C-B12B-C4A8814139F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).